RC case RC-B6SN — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/70dc0c20-b608-4da4-84a5-e9d6fca1879c

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1945; Vital status: Alive; Country of birth: United States.

Diagnoses (3)
1. Angioimmunoblastic T-cell lymphoma (the primary disease): ICD-O-3 morphology code: 9705/3; ICD-10 code: C84; Tissue or organ of origin: Lymph nodes of multiple regions; Site of resection or biopsy: Lymph nodes of inguinal region or leg; Classification of tumor: primary; Age at diagnosis: 69.0 years (25,202 days); Year of diagnosis: 2014; Method of diagnosis: Excisional Biopsy; Ann Arbor B symptoms: Yes; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: Yes; Ann arbor b symptoms described array: Fever / Weight Loss / Night Sweats; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High-Intermediate Risk; Sites of involvement: Lymph Node, Axillary / Lymph Node, Cervical / Lymph Node, Iliac-Common / Lymph Node, Inguinal / Lymph Node, Mediastinal / Spleen / Thyroid.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CHOP; Days to treatment start: 30 days; Days to treatment end: 142 days; Number of cycles: 6; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Days to treatment start: 193 days; Treatment outcome: Complete Response; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Romidepsin; Initial disease status: Progressive Disease; Days to treatment start: 857 days (2.3 years); Days to treatment end: 1,041 days (2.9 years); Number of cycles: 6; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: Post Initial Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Prior malignancy of the breast (histology not recorded by GDC). Laterality: Left; Age at diagnosis: 47.3 years (17,284 days); Year of diagnosis: 1993; Days to diagnosis: -7,918 days (-21.7 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -7,927 days (-21.7 years); Treatment anatomic sites: Breast.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cyclophosphamide + Fluorouracil + Methotrexate + Tamoxifen; Days to treatment start: -7,918 days (-21.7 years); Treatment anatomic sites: Body, total.
   Recorded as not given: Radiation Therapy, NOS.
3. Recurrence (histology not recorded by GDC). Age at diagnosis: 71.2 years (26,010 days); Days to diagnosis: 808 days (2.2 years).

Follow-up (5 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 100.
- Days to follow up: 95 days; Disease response: Tumor Free.
- Day 808 (recurrence): Progression or recurrence: Yes; Days to recurrence: 808 days (2.2 years).
- Day 1,007 (end of treatment course 1): Disease response: Tumor Free; Imaging type: PET; Imaging result: Negative.
- Day 2,679 (within 2 months after completion of first-course treatment): Disease response: Tumor Free; Imaging type: PET; Imaging result: Negative.

Molecular and laboratory tests
- Lactate Dehydrogenase 268 U/L [Blood test normal range upper: 250].
- Epstein-Barr Virus (ISH): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 67 kg; Height: 158 cm; BMI: 26.8.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Tobacco smoking quit year: 1980.

Family history
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Melanoma.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Melanoma.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B6SN-NB1-A: Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample RC-B6SN-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide RC-B6SN-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 7; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 1.
